Gene-level copy-number profile of tumor specimen TCGA-L5-A4OO-01A from TCGA case TCGA-L5-A4OO, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 76.0 years (27,757 days).
Specimen TCGA-L5-A4OO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.0116158a-ba5a-4cb5-a5f5-64d94dfb8b0d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OO-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dba0da6d-09db-4822-829f-9b31dfaf5062

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 94; copy number 1: 20,013; copy number 2: 37,168; copy number 3: 2,237; copy number 4: 239; copy number 6: 62.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A4OO-01A-11D-A25X-01): tumor purity 0.43, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 86 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:33,956,972–34,677,247, 4 genes (within-gene range 0–1): LINC01811, AC123023.2, AC123023.1, AC018359.1.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr10:80,776,165–81,875,133, 4 genes: FARSBP1, WARS2P1, RPA2P2, AL096706.1.
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–1): PTEN.
- chr10:87,945,502–88,700,401, 10 genes: RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1.
- chr10:88,727,485–88,728,914, 1 gene: KRT8P38.
- chr12:81,868,368–81,869,046, 1 gene: AC091515.1.
- chr12:83,021,890–89,709,300, 61 genes (within-gene range 0–1) (broad region; genes not listed).
- chr18:38,655,209–38,688,033, 1 gene: AC100781.1.
- chr20:15,280,764–15,280,873, 1 gene: RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 62 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:81,953,719–83,134,870, 10 genes, copy number 6 (within-gene range 0–6): LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2.
- chr19:33,555,568–33,815,763, 4 genes, copy number 6: AC010485.1, RPL21P131, CHST8, KCTD15.
- chr20:50,999,370–54,269,542, 48 genes, copy number 6: AL050404.1, KCNG1, AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1.

Autosomal genes at a single copy (total copy number 1): 17,634. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
